Gene-level copy-number profile of tumor specimen TCGA-OR-A5KB-01A from TCGA case TCGA-OR-A5KB, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 61.7 years (22,550 days).
Specimen TCGA-OR-A5KB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.f71a8133-9597-4e81-819e-485b523ae635.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5KB-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7a0a74e2-258f-49b6-a864-88d76d577e91

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 396; copy number 2: 13,530; copy number 3: 23,867; copy number 4: 15,574; copy number 5: 2,988; copy number 6: 3,355; copy number 7: 102.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5KB-01A-11D-A309-01): tumor purity 0.59, ploidy 3.35, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,992,543–140,992,659, 1 gene: Y_RNA.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 102 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:120,639,090–126,017,357, 59 genes, copy number 7 (within-gene range 2–7): AC025741.1, PRDM5, RNU6-550P, SETP12, NDNF, RN7SKP137, AC105254.1, AC105254.2, TNIP3, RNU6-948P, QRFPR, Y_RNA, AC093816.1, TUBB4BP5, ANXA5, TMEM155, PP12613, EXOSC9, CCNA2, BBS7, AC079341.1, TRPC3, AC097533.1, RN7SL335P, KIAA1109, ADAD1, IL2, IL21, IL21-AS1, AC053545.1, CETN4P, BBS12, AC021205.2, FGF2, AC021205.1, AC021205.3, NUDT6, SPATA5, AC026402.1, AC026402.2, SPRY1, AC093821.1, LINC02435, LINC01091, AC096732.1, RPL21P50, AC093767.1, AC108075.1, PPIAP76, AC121154.1, AC133530.1, TUBAP10, TECRP2, LINC02516, ANKRD50, FAT4, Y_RNA, MIR2054, AC104664.1.
- chr4:126,064,128–127,774,292, 13 genes, copy number 7: LINC02379, H3P15, AC097528.1, RBM48P1, Y_RNA, AC096773.1, AC093772.1, AC093772.2, AC097462.1, AC097462.2, AC097462.3, INTU, SLC25A31.
- chr9:101,125,436–101,125,921, 1 gene, copy number 7: AL161631.1.
- chr10:30,529,517–30,629,762, 6 genes, copy number 7 (within-gene range 4–7): AL590068.4, AL590068.1, RN7SL63P, AL590068.2, AL590068.3, LYZL2.
- chr22:34,756,676–35,704,176, 23 genes, copy number 7 (within-gene range 3–7): LINC02885, ISX, LINC01399, Z99755.2, Z99755.1, RNU7-167P, HMGXB4, AL008635.1, TOM1, MIR3909, MIR6069, Z82244.2, Z82244.1, HMOX1, MCM5, AL022334.1, AL022334.2, RASD2, MB, AL049747.1, APOL6, AL049748.1, MRPS16P3.

Autosomal genes at a single copy (total copy number 1): 396. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
